Somatic mutation profile of tumor specimen C3L-00444-08 (aliquot CPT0130600006) from CPTAC case C3L-00444, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 61.5 years (22,461 days).
Specimen C3L-00444-08: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf92b54b-e28a-46d5-8ff9-7fe1a84fb977.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00444-31 (Blood Derived Normal), aliquot CPT0130670001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5786e39d-bf44-41ab-872b-d41206afddec

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Intron 2, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 2, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HAGH | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.668); catalogued as rs143832024; called by muse, mutect2, varscan2
- MTRR | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 54/1034 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1327536759; called by muse, mutect2
- NIBAN1 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); catalogued as rs777078920; called by muse, mutect2, varscan2
- OR2G3 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs754133704, COSV100180524, COSV60680937, COSV60682135; called by muse, varscan2
- OTOA | c.2393C>T p.P798L (on ENST00000286149; = p.P784L on NM_144672.4) | Missense Mutation (SNP) | VAF 77/647 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs772182297; called by muse, mutect2, varscan2
- PACSIN1 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV55059553; called by muse, mutect2
- PCDH9 | c.1471A>G p.I491V | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.026); catalogued as rs751661836; called by muse, mutect2, varscan2
- PSMD1 | c.299T>A p.I100N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV58079898; called by muse, mutect2
- SETD2 | c.4885C>G p.H1629D | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57431577; called by muse, mutect2
- STXBP5 | c.2840G>A p.R947H (on ENST00000321680 / NM_001127715.2; = p.R911H on NM_139244.4) | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200165087; called by muse, mutect2, varscan2
- TAF5L | c.483C>A p.N161K | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.438); catalogued as rs1258731062; called by muse, mutect2
- TRO | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 68/381 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs753977149; called by muse, mutect2, varscan2
- ZNF529 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs746827271; called by muse, mutect2, varscan2
- ASGR2 | c.124+1G>T p.X42_splice | Splice Site (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- CYP11A1 | c.746A>G p.N249S | Missense Mutation (SNP) | VAF 66/502 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CYP4F22 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 56/469 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GRB14 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by mutect2, varscan2
- HIVEP2 | c.461dup p.I155Dfs*9 | Frame Shift Ins (INS) | VAF 27/163 reads (17%) | called by mutect2, pindel, varscan2
- HNF4A | c.723C>A p.D241E | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- MET | c.3017_3028+4del p.X1006_splice | Splice Site (DEL) | VAF 41/213 reads (19%) | called by mutect2, pindel, varscan2
- NOL3 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- OR14I1 | c.179T>A p.F60Y | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5D16 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- OTULINL | c.1024T>A p.S342T | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PKDREJ | c.690del p.V231Cfs*3 | Frame Shift Del (DEL) | VAF 29/214 reads (14%) | called by mutect2, pindel, varscan2
- PPP1R26 | c.667_670del p.E223Rfs*7 | Frame Shift Del (DEL) | VAF 34/330 reads (10%) | called by mutect2, pindel
- SLC20A2 | c.687dup p.V230Cfs*28 | Frame Shift Ins (INS) | VAF 40/268 reads (15%) | called by mutect2, varscan2
- SMCR8 | c.1759A>T p.I587F | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- SPATA18 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1QTNF6 | c.414G>C p.P138= | Silent (SNP) | VAF 34/232 reads (15%) | catalogued as COSV55397484; called by muse, mutect2, varscan2
- CAMK4 | c.63G>A p.A21= | Silent (SNP) | VAF 72/412 reads (17%) | catalogued as rs746314655; called by muse, mutect2, varscan2
- CCN2 | c.1014G>A p.S338= | Silent (SNP) | VAF 28/201 reads (14%) | called by muse, mutect2, varscan2
- HAUS7 | c.1032C>T p.G344= | Silent (SNP) | VAF 74/442 reads (17%) | catalogued as rs969570085, COSV57848008; called by muse, mutect2, varscan2
- LAMB4 | c.3811C>T p.L1271= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99223331; called by muse, mutect2, varscan2
- MTHFR | c.120G>A p.E40= | Silent (SNP) | VAF 220/638 reads (34%) | catalogued as rs1394958095; called by muse, mutect2, varscan2
- TRPV1 | c.336C>G p.L112= | Silent (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2
- ZGPAT | c.999G>A p.T333= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs370638446; called by muse, mutect2, varscan2
- C1orf54 | c.*84A>T | 3'UTR (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- CORO6 | c.-63A>T | 5'UTR (SNP) | VAF 24/118 reads (20%) | called by muse, mutect2, varscan2
- GPR137 | c.-7C>G | 5'UTR (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- NPC2 | c.441+25dup | Intron (INS) | VAF 28/279 reads (10%) | called by mutect2, pindel, varscan2
- TEAD3 | c.330+199C>T | Intron (SNP) | VAF 50/396 reads (13%) | called by muse, mutect2, varscan2
